Surgical pathology report (de-identified scan), TCGA case TCGA-CG-5721, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-5721-01A (Primary Tumor).

*** Diagnosis(es): ***

1. Distal gastric section with an ulcerated gastric carcinoma of maximum diameter 7.5 cm extending up to 5 cm from the oral and 4 cm from the aboral resection margin and localized on the greater curvature side, of the histological type of a moderately differentiated adenocarcinoma (gastric carcinoma of the intestinal type). Invasive tumor dissemination within all gastric wall layers into the perigastric fatty tissue, subserosa and localized contiguous infiltration of all wall layers of the transverse colon adhering to the gastric wall with the formation of a gastrocolic fistula.

Oral and aboral resection margin of the distal gastric resection specimen as well as of the colon and greater omentum tumor-free.

One of nineteen perigastric and mesocolic lymph nodes with metastasis from the gastric carcinoma and otherwise uncharacteristically reactive changes.

Antral mucosa with fairly minor, florid, moderately chronic gastritis and foveolar hyperplasia, and corpus mucosa with non-florid, fairly minor chronic gastritis of the superficial type with evidence of *Helicobacter pylori*.

2.: Small wedge excision specimen of the liver including a subcapsularly localized biliary hamatoma (von Meyenburg complex).

3.: Proximal partial gastric resection specimen including the esophageal cuff without further fragments of the carcinoma mentioned under 1.

4.: Five tumor-free lymph nodes (hepatic artery) with uncharacteristically reactive changes.

Therefore tumor stage: pT4 pN1 (1/24), ■

Source: NCI Genomic Data Commons file 35c8f997-979d-4cf2-b880-e900cbef08bc (TCGA-CG-5721.BBC8E198-219D-47FD-9904-506BE9C139DC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).